Somatic mutation profile of tumor specimen TCGA-DH-A669-01A (aliquot TCGA-DH-A669-01A-12D-A31L-08) from TCGA case TCGA-DH-A669, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 70.7 years (25,809 days).
Specimen TCGA-DH-A669-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96b0fcde-c804-4e3c-aa17-1ce7bfff03a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A669-10A (Blood Derived Normal), aliquot TCGA-DH-A669-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c7df496-7887-443f-a25c-fc83a8f6a815

The open-access MAF lists 61 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 41, Silent 12, Splice Site 3, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/64 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SETD2 | c.4808A>G p.H1603R | Missense Mutation (SNP) | VAF 23/131 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57434464; called by muse, mutect2, varscan2
- ABCA7 | c.4264C>T p.R1422* | Nonsense Mutation (SNP) | VAF 39/92 reads (42%) | catalogued as rs999041739, COSV99566277; called by muse, mutect2
- ABCC11 | c.3461C>A p.T1154K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV100750965; called by muse, mutect2, varscan2
- BOD1L1 | c.7631G>A p.G2544E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1208256175, COSV99239860; called by muse, mutect2, varscan2
- BTBD7 | c.173dup p.R59Efs*14 | Frame Shift Ins (INS) | VAF 73/186 reads (39%) | catalogued as rs752512017; called by mutect2, varscan2
- CD300LF | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV100042822; called by muse, mutect2, varscan2
- CDH12 | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101202942; called by muse, mutect2, varscan2
- CMAS | c.221G>C p.W74S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99982707; called by muse, mutect2, varscan2
- COQ5 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1246418745, COSV99942397; called by muse, mutect2, varscan2
- CROCC | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.402); catalogued as rs748300745, COSV65013952; called by muse, mutect2, varscan2
- DHX16 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.375); catalogued as COSV100906112; called by muse, mutect2
- DPY19L4 | c.637T>G p.S213A | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV101363381; called by muse, mutect2, varscan2
- DYNC1I2 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99784079; called by muse, mutect2, varscan2
- DYRK1A | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs374771208; ClinVar: likely benign; called by muse, mutect2, varscan2
- EEF1A1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58548900; called by muse, mutect2, varscan2
- FLRT2 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.76); catalogued as COSV100420681; called by muse, mutect2, varscan2
- GIMAP7 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs199951983, COSV100543700; called by muse, mutect2, varscan2
- GRM2 | c.2545+2T>A p.X849_splice | Splice Site (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99622998; called by muse, mutect2, varscan2
- HAUS1 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV99959056; called by muse, mutect2, varscan2
- ITPR3 | c.2356G>A p.V786M | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs577602247, COSV100967646; called by muse, mutect2, varscan2
- KRT6C | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99360081; called by muse, mutect2, varscan2
- L3MBTL4 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 82/93 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99529920; called by muse, mutect2, varscan2
- LGR5 | c.1486A>G p.N496D | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57005656; called by muse, mutect2, varscan2
- LILRB1 | c.646G>A p.A216T (on ENST00000427581; = p.A180T on NM_006669.6) | Missense Mutation (SNP) | VAF 93/128 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750303692, COSV100207544; called by muse, varscan2
- LYPD6B | c.202G>A p.A68T (on ENST00000409029 / NM_001317004.1; = p.A92T on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs746167432, COSV54519320; called by muse, mutect2, varscan2
- MRPL15 | c.666C>G p.Y222* | Nonsense Mutation (SNP) | VAF 7/97 reads (7%) | catalogued as COSV99477587; called by muse, mutect2
- NOL4L | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779165706, COSV100675542; called by muse, mutect2, varscan2
- NOL6 | c.3211C>T p.L1071F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53043023; called by mutect2, varscan2
- NPAP1 | c.465A>T p.E155D | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV61505896; called by muse, mutect2
- NPIPB15 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.107); catalogued as rs760667269, COSV70438555; called by muse, mutect2, varscan2
- NTRK1 | c.1793A>G p.N598S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs1340832515, COSV100693581; called by muse, mutect2, varscan2
- OR10K1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as COSV99193775; called by muse, mutect2
- PARP12 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs761991030, COSV99694184; called by muse, mutect2, varscan2
- RAB27A | c.526A>T p.M176L | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs757760608, COSV100389434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM46 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV55977570; called by muse, mutect2, varscan2
- SEMA3E | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as rs1192155437, COSV100319057; called by muse, mutect2, varscan2
- SZT2 | c.5088+1G>A p.X1696_splice (on ENST00000634258 / NM_001365999.1; = p.X1639_splice on NM_015284.4) | Splice Site (SNP) | VAF 87/96 reads (91%) | catalogued as COSV100987484; called by muse, mutect2, varscan2
- TAAR2 | c.209A>G p.Y70C (on ENST00000367931 / NM_001033080.1; = p.Y25C on NM_014626.3) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99255703; called by muse, mutect2, varscan2
- TDRD6 | c.4241T>C p.L1414S | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100287927; called by muse, mutect2, varscan2
- TG | c.7784A>G p.D2595G | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV99601973; called by muse, mutect2, varscan2
- TRIML2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1464457758, COSV58720914; called by muse, mutect2, varscan2
- UGT1A8 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs549093448, COSV100990574; called by muse, mutect2, varscan2
- ZDHHC14 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 61/103 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100399327; called by muse, mutect2, varscan2
- ZIC4 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101268053; called by muse, mutect2, varscan2
- RB1 | c.719-1_736del p.X240_splice | Splice Site (DEL) | VAF 20/25 reads (80%) | called by mutect2, pindel
- SETD2 | c.7037_7040dup p.Q2347Hfs*23 | Frame Shift Ins (INS) | VAF 27/63 reads (43%) | called by mutect2, pindel, varscan2
- SYNRG | c.3202G>A p.G1068R | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF780B | c.1714del p.N573Ifs*94 | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | called by mutect2, varscan2
- CCDC185 | c.1812C>T p.S604= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100838814; called by muse, mutect2, varscan2
- DDX19A | c.912T>C p.D304= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as rs1065168; called by muse, mutect2, varscan2
- ERN2 | c.612C>T p.C204= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs774207313, COSV99891873; called by muse, mutect2, varscan2
- H1-4 | c.108T>A p.S36= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV99175299; called by muse, mutect2, varscan2
- IGLV3-12 | c.102A>G p.A34= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- KIRREL1 | c.1308G>A p.G436= | Silent (SNP) | VAF 16/171 reads (9%) | catalogued as COSV100780010; called by muse, mutect2
- LAMB2 | c.3756C>T p.A1252= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs773560262, COSV100026334; called by muse, mutect2, varscan2
- NOL4L | c.1221G>A p.V407= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV100675656; called by muse, mutect2, varscan2
- OR51B5 | c.366T>A p.I122= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100332606; called by muse, mutect2, varscan2
- PBRM1 | c.2223G>A p.P741= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs759730545, COSV56294143; called by muse, mutect2, varscan2
- PCED1B | c.882A>G p.L294= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs926990474, COSV101423674; called by muse, mutect2
- RHBDF1 | c.1740C>T p.S580= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs770682385, COSV51957535; called by muse, mutect2, varscan2
